Somatic mutation profile of tumor specimen TCGA-V1-A9Z8-01A (aliquot TCGA-V1-A9Z8-01A-11D-A41K-08) from TCGA case TCGA-V1-A9Z8, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9Z8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 222d2aff-1c70-4d2d-9997-b2c95de35614.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9Z8-10A (Blood Derived Normal), aliquot TCGA-V1-A9Z8-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1a8b11c-9cf1-4c8e-a81d-3ae70ecafff5

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 14, Silent 6, Frame Shift Del 3, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO5 | c.2105T>C p.I702T | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs761257306, COSV100201283; called by muse, mutect2, varscan2
- CCNL2 | c.531A>G p.I177M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101275628; called by mutect2, varscan2
- CEP104 | c.2048G>A p.R683Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140499832; called by muse, mutect2, varscan2
- COL5A1 | c.941C>A p.P314H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV100879333, COSV65668954; called by muse, mutect2, varscan2
- CYFIP2 | c.899A>T p.K300M | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1314336556, COSV100555394; called by muse, mutect2
- KCNQ3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs774311301, COSV66468995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRAP | c.1642A>G p.K548E (on ENST00000359988 / NM_001322945.2; = p.K513E on NM_006175.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV63493085; called by muse, mutect2
- RFX3 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV100174386; called by muse, mutect2
- RP1 | c.5387C>T p.T1796M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs764959789, COSV55113518; called by muse, mutect2, varscan2
- RWDD3 | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99811454; called by muse, mutect2, varscan2
- SIPA1L1 | c.902A>G p.N301S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0.039); catalogued as rs756201714, COSV100665003; called by muse, mutect2, varscan2
- ST6GAL2 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | PolyPhen probably damaging (0.988); catalogued as COSV64527367; called by muse, mutect2, varscan2
- TBX3 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99983265, COSV99983465; called by muse, mutect2, varscan2
- UBR2 | c.1475G>A p.W492* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100867320; called by muse, mutect2, varscan2
- WDPCP | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs769734014, COSV55413573, COSV55416212; called by muse, mutect2, varscan2
- CCNL2 | c.323_331del p.R108_Y111delinsH | In Frame Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- FLG | c.5331del p.A1778Pfs*56 | Frame Shift Del (DEL) | VAF 20/206 reads (10%) | called by mutect2, pindel
- MOV10L1 | c.2114del p.E705Gfs*19 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- PRDM16 | c.3279del p.K1094Nfs*17 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- RB1 | c.1010dup p.L337Ffs*4 | Frame Shift Ins (INS) | VAF 23/106 reads (22%) | called by mutect2, pindel, varscan2
- CORO7 | c.2370C>T p.C790= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs768413907, COSV52029693; called by muse, mutect2, varscan2
- MAST3 | c.2839C>T p.L947= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV99444101; called by muse, mutect2
- PAGE2B | c.261T>A p.G87= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV100894276; called by muse, mutect2, varscan2
- PLXNA4 | c.507C>G p.V169= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100321919, COSV58130643; called by muse, mutect2, varscan2
- SPTAN1 | c.4176T>G p.A1392= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100823170; called by muse, mutect2, varscan2
- XIRP2 | c.6003C>T p.Y2001= (on ENST00000628543; = p.Y2176= on NM_152381.6) | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs759163543, COSV99737214; called by muse, mutect2, varscan2
